Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PX, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PX-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED] Accession #: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED] Service Date: [REDACTED]
DOB: [REDACTED] Sex: Male Received: [REDACTED]
Soc. Sec. #: [REDACTED] Location: [REDACTED] Client: [REDACTED]
Physician(s): [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

Right kidney, radical nephrectomy: Multifocal papillary renal cell carcinoma, Fuhrman grade 3, 4.2 cm largest tumor size, negative margins.

COMMENT:

Kidney Tumor Synoptic Comment

- **Histologic type:** Renal cell carcinoma, papillary type.
- **Grade:** Fuhrman grade 3.
- **Tumor size:** Three distinct separate tumor masses are present, the largest is 4.2 cm.
- **Sites within kidney:** Upper pole, lower pole, mid kidney.
- **Renal pelvis:** Normal.
- **Ureter:** Normal.
- **Renal sinus:** Normal.
- **Hilar renal veins:** Normal.
- **Intrarenal veins and lymphatics:** Normal.
- **Adrenal gland:** Not present.
- **Capsule/perirenal fat:** Tumor does not penetrate capsule.
- **Lymph node status:** Negative, total number of nodes examined : 2.
- **Resection margins:**
- **Ureter:** Negative (tumor is greater than 1 cm from margin).
- **Renal vein:** Negative (tumor is greater than 1 cm from margin).
- **Soft tissue:** Negative (tumor is 0.1 cm from margin).
- **AJCC Stage:** pT1N0MX.

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site: R Kidney NOS C64.9
06/23/2014

Specimen(s) Received
A: Right kidney (fresh)

Clinical History

[page 2 of 2]
Page 2 of 2

Source: NCI Genomic Data Commons file a6304212-50b6-4b81-827b-35f536102c8e (TCGA-UZ-A9PX.D4B5B70A-ED8A-4016-98DD-88E15A9B808D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).